Surgical pathology report (de-identified scan), TCGA case TCGA-53-7813, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Miami, specimen TCGA-53-7813-01A (Primary Tumor).

[page 1 of 3]
Name:
DOB:
Gender: F
MRN:
Location:
Physician:

Case #:
Collected:
Received:
Reported:
Copy To:

Pathologic Interpretation:

- A. Wedge resection right upper lobe, [REDACTED]
- Moderately differentiated adenocarcinoma of lung, 1.5 cm in greatest dimension.
- Multiple microscopic foci of bronchioalveolar carcinoma are present, including in the stapled resection margin.
- B. Hilar lymph node, 10:
- One lymph node, no tissue seen.
- C. Right lower paratracheal, 4R:
- One lymph node, no tissue seen.
- D. Subcarinal lymph node, 7:
- One lymph node, no tissue seen.
- E. Inferior pulmonary ligament lymph node, 9:
- One lymph node, no tissue seen.
- F. Parabronchial lymph node, 11:
- One lymph node, no tissue seen.
- G. Right upper lobe:
- Multiple microscopic foci of bronchioalveolar carcinoma.
- Atypical pneumocyte hyperplasia.
- H. Right upper lobe bronchial margin:
- Segment of bronchus, no tumor seen.

Tumor Summary:

Specimen Type
- Lobectomy.

Laterality
- Right.

Tumor Site
- Upper lobe.

Tumor Size
- Greatest dimension: 1.5 cm.

Histologic Type
- Adenocarcinoma, not otherwise characterized.
- Bronchioloalveolar carcinoma

Histologic Grade
- G2: Moderately differentiated.

Margins
- Cannot be assessed.

Direct extension of tumor: The visceral pleura is not involved by tumor.

Venous (Large Vessel) Invasion (V)
- Absent.

[page 2 of 3]
Arterial (Large Vessel) Invasion.
Absent.

Lymphatic (Small Vessel) Invasion (L):
- Absent.

Regional Lymph nodes (pN):
Number examined: 5.
Number involved: 0.

Pathologic Staging (pTNM)
PT1 N pN0 pMX

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

Electronically Signed Out By

Intraoperative Consultation

Wedge resection right upper lobe, Adenocarcinoma. Multiple foci of bronchoalveolar carcinoma in margins.

Clinical History:

None Provided

Operation Performed

Right thoracotomy

Pre Operative Diagnosis:

Right upper lobe lesion

Specimen(s) Received:

- A: Wedge resection right upper lobe, FS
- B: Hilcu lymph node, 10
- C: Right lower paratracheal, 4R
- D: Subcortical lymph node, 7
- E: Inferior pulmonary ligament lymph node, 9
- F: Parabronchial lymph node, 11
- G: Right upper lobe
- H: Right upper lobe bronchial margin

Gross Description:

- A. Received fresh for frozen section is a 50 gram wedge resection specimen. There is a 1.5 x 1.3 x 1.3 cm lobulated tan, firm lesion. The specimen measures 7.0 x 5.0 x 4.0 cm and has extensive metal staples throughout the perimeter. Sections are submitted as follows:
- 1 Section through lesion for frozen section

[page 3 of 3]
- 2&3 Margins for frozen sections
- 4-7 Mass lesions, submitted in toto
- 8 Satellite nodules immediately adjacent to mass lesion
- 9&10 Lung parenchyma distant to mass

- B. Received in formalin is a tan-white soft tissue specimen that measures 1.3 x 0.6 x 0.6 cm. Bisected and submitted in toto in one cassette.
- C. Received in formalin is a 1.5 x 1.0 x 0.5 cm fibrofatty specimen that has been bisected and submitted in toto in one cassette.
- D. Received in formalin is a 1.0 x 1.0 x 1.0 cm fibrofatty specimen that has potential lymph tissue, submitted and bisected in toto in one cassette.
- E. Received in formalin is a 1.0 x 0.5 x 0.5 cm fibrofatty specimen that has been bisected and submitted in toto in one cassette.
- F. Received in formalin is a 0.5 x 0.5 x 0.3 cm soft tissue specimen that has been submitted in toto in one cassette.
- G. Received in formalin is a 114 grams partial lobectomy specimen, measuring 12.0 x 5.0 x 3.0 cm. The specimen has been serially sectioned to reveal a soft, hyperemic spongy mucosa with no masses present. Sections submitted as follows:
- 1 Bronchial and vascular margins
- 2-6 Non adjacent section throughout parenchyma
- 7-11 Additional sections of consolidated areas.
- H. Received in formalin is a 1.5 x 1.0 x 0.5 cm soft tissue specimen that has been submitted in one cassette.

Source: NCI Genomic Data Commons file 31bb766b-7a6f-47ec-adad-117ef248687b (TCGA-53-7813.BDA037B7-AC21-42C0-95C1-C546F0ACE670.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).